Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A7AW, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A7AW-01A (Primary Tumor).

[page 1 of 3]
(192.0cm 75.4kg BSA: 2.01m²)

Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

Supplemental report to follow.

(B) BILATERAL PELVIC LYMPH NODES:

METASTATIC ADENOCARCINOMA IN ONE OF NINE LYMPH NODES. (1/9)

METASTATIC FOCUS MEASURES 6.0 MM.

No extranodal extension present.

Entire report and diagnosis completed by

CLU ICD-O-3
Adenocarcinoma, acinar
8/40/13

path
Adenocarcinoma NOS
8/40/13
Site: Prostate NOS
8/22/13
C61.9

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES - Supplemental report to follow.

(B) BILATERAL PELVIC LYMPH NODES - Multiple fibroadipose soft tissue fragments (3 x 2.9 x 1 cm in aggregate). Dissection reveals 9 lymph nodes ranging from 0.5 x 0.4 x 0.3 cm to 1.7 x 0.6 x 0.4 cm. The lymph nodes are submitted entirely.

SECTION CODE: B1, five lymph nodes; B2, three lymph nodes; B3, one lymph node, bisected.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

Start of ADDENDUM

[page 2 of 3]
[REDACTED] (192.0cm 75.4kg BSA: 2.01m²)

Specimen Date/Time: [REDACTED]

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

(A) PROSTATE AND SEMINAL VESICLES:

PROSTATIC ADENOCARCINOMA GLEASON SCORE 7 (4+3). (SEE COMMENT)

EXTENSIVE EXTRAPROSTATIC EXTENSION PRESENT.

MARGINS OF RESECTION FREE OF TUMOR.

Right and left seminal vesicles, no tumor present.

Segments of right and left vasa deferentia, no tumor present.

PERINEURAL AND LYMPHOVASCULAR INVASION PRESENT.

PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH-GRADE.

SEE PREVIOUS REPORT FOR DIAGNOSIS OF PELVIC LYMPH NODES.

COMMENT

The prostate gland contains three foci of prostatic adenocarcinoma, two in the peripheral zone and one in the transition zone. The dominant tumor focus is located in the right lateral, right posterolateral and right posterior peripheral zone. This tumor focus measures 2.5 x 0.6 cm in the largest cross-sectional dimension and it is present in the four cross sections of the prostate, extensively in the apex and focally in the base region. The tumor exhibits extensive multifocal extraprostatic extension. Extraprostatic extension is present in the right lateral, right posterolateral surface of the prostate and right superior neurovascular bundle region. The added length of extraprostatic extension is 23.0 mm. The margins of resection are free of tumor. The second tumor focus is located in the left lateral and left posterolateral peripheral zone. This tumor focus measures 1.0 x 0.1 cm in the largest cross-sectional dimension and it is present in two cross sections. The third tumor focus is located in the left transition zone. This tumor focus measures less than 0.1 x less than 0.1 cm in the largest cross-sectional dimension and it is present in one cross section. The nondominant tumor foci of lower histologic grade and confined to the prostate. All margins of resection are free of tumor.

Please refer to the previous report for the diagnosis of the pelvic lymph nodes.

GROSS DESCRIPTION

(A) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.6 x 3.4 x 3.7 cm, 36 grams, post fixation) has the usual shape. The soft tissue present along the posterolateral aspects of the prostate is scant and symmetrical. Firmness is noted on the right mid region of the prostate. Serial cross sections after fixation demonstrate an area consistent with tumor in the right side of the first three of the four cross sections

[page 3 of 3]
(192.0cm 75.4kg BSA: 2.01m²)

Specimen Date/Time:

of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

Also included in the container are three separate fragments of tissue, two consistent with segments of vas (4.5 x 0.5 x 0.3 cm and 3.5 x 0.3 x 0.2 cm) and one consistent with adipose tissue (1.8 x 1.2 x 0.3 cm).

SECTION CODE: A1, A2, detached fragments of tissue; A3, A4, base of right seminal vesicle and right vas deferens; A5, A6, base of left seminal vesicle and left vas deferens; A7, prostatic base, right border; A8, A9, prostatic base, right posterior border; A10-A14, prostatic base, central portion; A15, A16, prostatic base, left border; A17, A18, prostatic base, left posterior border; A19, apex anterior; A20, apex left; A21, A22, apex posterior; A23, apex right; A24-A39, sections of the four cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (A20) denotes surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by

-----END OF REPORT-----

IIHAA Discrepancy		☒

Source: NCI Genomic Data Commons file 29aca16d-5aaa-4679-9aae-efc9a12a4e46 (TCGA-KK-A7AW.B5E8DF63-7C54-4D45-93ED-5C80075C63A5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).